Gene-level copy-number profile of tumor specimen TCGA-F5-6571-01A from TCGA case TCGA-F5-6571, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.1 years (22,666 days).
Specimen TCGA-F5-6571-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.5ebade4e-8214-4900-b467-db533699702e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F5-6571-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30fe780b-78d8-4aff-9c71-c43b814f1da6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,207; copy number 2: 44,465; copy number 3: 831; copy number 4: 111; copy number 6: 2,049; copy number 7: 60; copy number 9: 53; copy number 10: 22; copy number 12: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F5-6571-01A-12D-1825-01): tumor purity 0.76, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,204 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–56,216,942, 731 genes, copy number 6–12 (broad region; genes not listed).
- chr13:57,204,379–57,729,311, 5 genes, copy number 6 (within-gene range 4–6): MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1.
- chr13:67,121,081–67,911,951, 8 genes, copy number 6 (within-gene range 4–6): AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P.
- chr13:69,700,594–83,145,903, 141 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr13:85,046,001–85,969,533, 8 genes, copy number 6: AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1, MOB1AP1.
- chr13:88,142,867–103,444,968, 214 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:104,814,327–114,337,626, 162 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:25,762,384–64,313,132, 935 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
